Somatic mutation profile of tumor specimen TCGA-BK-A139-01C (aliquot TCGA-BK-A139-01C-08D-A272-09) from TCGA case TCGA-BK-A139, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IB; Tumor grade: G3; Age at diagnosis: 74.1 years (27,077 days).
Specimen TCGA-BK-A139-01C: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 16ca9b39-5202-4574-837b-3835068f2cc1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BK-A139-10A (Blood Derived Normal), aliquot TCGA-BK-A139-10A-01D-A272-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/50c67a0f-0f88-4ae5-995e-7006f054674f

The open-access MAF lists 90 somatic variants for this specimen: 66 protein-altering or splice-affecting, 23 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 61, Silent 23, Nonsense Mutation 2, Frame Shift Del 1, In Frame Del 1, RNA 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3R1 | c.1717_1722del p.L573_R574del (on ENST00000521381 / NM_181523.3; = p.L303_R304del on NM_181504.4) | In Frame Del (DEL) | VAF 10/31 reads (32%) | hotspot (GDC flag); catalogued as COSV57129439; called by mutect2, pindel, varscan2
- TP53 | c.844C>T p.R282W | Missense Mutation (SNP) | VAF 9/29 reads (31%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs28934574, CM056413, CM920678, COSV52662048, COSV52662222, COSV52701296; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- AP3M2 | c.422G>A p.R141Q | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated (0.12); PolyPhen benign (0.223); catalogued as rs756052697, COSV51529483; called by mutect2, varscan2
- ASGR2 | c.154C>T p.R52C | Missense Mutation (SNP) | VAF 40/67 reads (60%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.982); catalogued as rs775565123, COSV54690086; called by muse, varscan2
- ASH2L | c.1849G>A p.E617K | Missense Mutation (SNP) | VAF 16/91 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.152); catalogued as COSV51698421; called by muse, mutect2, varscan2
- AXDND1 | c.2294G>T p.C765F | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.547); catalogued as rs1328041323, COSV62642011; called by muse, mutect2, varscan2
- CAPRIN1 | c.1760A>G p.H587R | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT tolerated (0.35); PolyPhen probably damaging (0.992); catalogued as rs759068488, COSV58219562; called by muse, mutect2, varscan2
- CBX6 | c.1085T>A p.M362K | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV53320749; called by muse, mutect2, varscan2
- CCDC82 | c.1121T>C p.L374P | Missense Mutation (SNP) | VAF 19/108 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1182611261, COSV53593198; called by muse, mutect2, varscan2
- DOCK7 | c.4833T>A p.F1611L (on ENST00000635253 / NM_001367561.1; = p.F1580L on NM_033407.3) | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.561); catalogued as COSV52003612; called by muse, mutect2, varscan2
- DPP9 | c.841G>A p.D281N (on ENST00000598800; = p.D310N on NM_139159.5) | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as rs764719635; called by muse, mutect2, varscan2
- DSC2 | c.185A>G p.N62S | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated (0.64); PolyPhen benign (0.034); catalogued as COSV51864126; called by mutect2, varscan2
- DYNLRB1 | c.286G>A p.E96K | Missense Mutation (SNP) | VAF 17/82 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.509); catalogued as rs573896721, COSV64063820; called by muse, varscan2
- ELF5 | c.212A>T p.E71V (on ENST00000312319 / NM_198381.2; = p.E61V on NM_001422.4) | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV56628736; called by muse, mutect2, varscan2
- EVC2 | c.231C>A p.D77E | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0.014); catalogued as rs776531365, COSV60388298; called by mutect2, varscan2
- FAM135B | c.1702C>T p.P568S | Missense Mutation (SNP) | VAF 5/50 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.048); catalogued as rs191933472; called by mutect2, varscan2
- FAM151B | c.379C>T p.P127S | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as COSV56472878; called by muse, mutect2, varscan2
- FAT3 | c.4670A>G p.E1557G | Missense Mutation (SNP) | VAF 15/73 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); catalogued as COSV99961793; called by muse, mutect2, varscan2
- FOXF2 | c.1327G>A p.V443I | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as rs181428616, COSV52525311; called by mutect2, varscan2
- FOXR1 | c.740G>A p.R247Q | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT tolerated (0.08); PolyPhen benign (0.081); catalogued as rs150635174, COSV57652017; called by muse, mutect2, varscan2
- GSAP | c.2294G>T p.R765I | Missense Mutation (SNP) | VAF 26/46 reads (57%) | SIFT deleterious (0); PolyPhen benign (0.246); catalogued as rs1201603617, COSV57529582; called by muse, mutect2, varscan2
- HELT | c.589C>T p.P197S | Missense Mutation (SNP) | VAF 11/22 reads (50%) | SIFT tolerated (0.05); PolyPhen benign (0); catalogued as COSV58819880; called by muse, mutect2, varscan2
- KCNN1 | c.1180G>A p.A394T | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT tolerated (0.16); PolyPhen benign (0.229); catalogued as rs1260374056, COSV55838552; called by muse, mutect2, varscan2
- KCTD17 | c.334G>A p.A112T | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV63248902; called by muse, mutect2
- KDM3B | c.1376G>A p.G459E | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.998); catalogued as rs1561770083, COSV58690112; called by muse, mutect2, varscan2
- L3MBTL4 | c.1007A>C p.K336T | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT tolerated (0.55); PolyPhen benign (0.115); catalogued as COSV53118685; called by muse, mutect2, varscan2
- LCE2B | c.236G>A p.R79H | Missense Mutation (SNP) | VAF 22/62 reads (35%) | SIFT tolerated, low confidence (0.66); PolyPhen benign (0); catalogued as rs767189385, COSV64227613; called by muse, mutect2, varscan2
- LGI4 | c.370C>T p.R124C | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as rs144343503, COSV100032601; called by muse, mutect2, varscan2
- LONP2 | c.1464A>G p.I488M | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV53522139; called by muse, mutect2, varscan2
- MTMR10 | c.931C>T p.Q311* | Nonsense Mutation (SNP) | VAF 4/18 reads (22%) | catalogued as COSV58727977; called by muse, varscan2
- MUC16 | c.29864C>T p.T9955I | Missense Mutation (SNP) | VAF 16/125 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.976); catalogued as COSV67449074, COSV67465843, COSV67502802; called by muse, mutect2, varscan2
- MUC17 | c.6913G>T p.D2305Y | Missense Mutation (SNP) | VAF 36/89 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.262); catalogued as COSV60287027; called by muse, mutect2, varscan2
- MYO1H | c.2080C>T p.R694C | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs764150151, COSV60443340; called by mutect2, varscan2
- NRG1 | c.1451C>A p.P484Q (on ENST00000405005 / NM_013964.5; = p.P489Q on NM_013956.5) | Missense Mutation (SNP) | VAF 19/34 reads (56%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.987); catalogued as COSV55157105; called by muse, mutect2, varscan2
- OCIAD1 | c.244G>C p.A82P | Missense Mutation (SNP) | VAF 28/80 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV51900609; called by muse, mutect2, varscan2
- OR8K1 | c.715G>T p.G239W | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV54402287, COSV54403778; called by muse, mutect2, varscan2
- OSMR | c.140G>T p.S47I | Missense Mutation (SNP) | VAF 28/182 reads (15%) | SIFT tolerated (0.25); PolyPhen benign (0.05); catalogued as COSV57084303; called by muse, varscan2
- PCNX4 | c.2882T>C p.I961T (on ENST00000406854 / NM_001330177.2; = p.I727T on NM_022495.5) | Missense Mutation (SNP) | VAF 37/81 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.339); catalogued as COSV58303752; called by muse, mutect2, varscan2
- POLR3B | c.2809C>T p.R937* | Nonsense Mutation (SNP) | VAF 8/40 reads (20%) | catalogued as rs763154774, COSV57284370; called by muse, mutect2, varscan2
- PRDM14 | c.631C>A p.P211T | Missense Mutation (SNP) | VAF 16/66 reads (24%) | SIFT tolerated (0.31); PolyPhen benign (0.018); catalogued as COSV52571980; called by muse, mutect2, varscan2
- PTPRN2 | c.318C>A p.D106E | Missense Mutation (SNP) | VAF 27/73 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.009); catalogued as COSV101233607; called by muse, mutect2, varscan2
- RASA1 | c.2120G>C p.R707P | Missense Mutation (SNP) | VAF 3/47 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV57192982, COSV99169644; called by muse, mutect2
- SIGLEC8 | c.202C>T p.R68W | Missense Mutation (SNP) | VAF 25/89 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.228); catalogued as rs746803267, COSV100367206, COSV58471655; called by muse, mutect2, varscan2
- SLITRK1 | c.1319G>T p.R440L | Missense Mutation (SNP) | VAF 13/69 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.081); catalogued as COSV65674743; called by muse, mutect2, varscan2
- SLITRK6 | c.1483A>G p.T495A | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT tolerated (0.87); PolyPhen benign (0); catalogued as rs1263803803; called by muse, mutect2, varscan2
- SMR3A | c.45del p.C16Vfs*106 | Frame Shift Del (DEL) | VAF 17/111 reads (15%) | catalogued as COSV56949617, COSV56950143; called by mutect2, pindel, varscan2
- ST18 | c.4G>C p.D2H | Missense Mutation (SNP) | VAF 33/107 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as COSV52491859; called by muse, mutect2, varscan2
- TECTA | c.1114G>T p.G372C | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.961); catalogued as COSV50703368; called by muse, mutect2, varscan2
- TMC7 | c.652G>T p.V218L | Missense Mutation (SNP) | VAF 17/66 reads (26%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as COSV58583118; called by muse, mutect2, varscan2
- TRIM69 | c.834T>C p.H278= (on ENST00000329464 / NM_182985.5; = p.H119= on NM_080745.5) | Splice Region (SNP) | VAF 12/57 reads (21%) | catalogued as rs1264818442, COSV57803580; called by muse, mutect2, varscan2
- TTC17 | c.190C>G p.H64D | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.942); catalogued as COSV50008171; called by muse, mutect2, varscan2
- TUBA3C | c.362G>A p.R121Q | Missense Mutation (SNP) | VAF 16/73 reads (22%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.037); catalogued as rs778228340, COSV67139976; called by muse, mutect2, varscan2
- ZNF786 | c.1479G>T p.E493D | Missense Mutation (SNP) | VAF 17/24 reads (71%) | SIFT deleterious (0.01); PolyPhen benign (0.034); catalogued as COSV60275865; called by muse, mutect2, varscan2
- ACSL1 | c.215G>C p.R72T | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT tolerated (0.14); PolyPhen benign (0.063); called by muse, mutect2, varscan2
- AHNAK2 | c.11993T>C p.V3998A | Missense Mutation (SNP) | VAF 8/91 reads (9%) | SIFT tolerated (0.43); PolyPhen benign (0.413); called by muse, mutect2
- CCDC114 | c.1438A>T p.R480W | Missense Mutation (SNP) | VAF 14/72 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.792); called by muse, mutect2, varscan2
- DNAJA2 | c.112G>C p.D38H | Missense Mutation (SNP) | VAF 4/54 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- DSEL | c.2599A>T p.I867F | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.615); called by muse, mutect2, varscan2
- NBAS | c.3308T>C p.L1103S | Missense Mutation (SNP) | VAF 16/74 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NFKB1 | c.214G>T p.A72S (on ENST00000394820 / NM_001382627.1; = p.A73S on NM_003998.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 8/67 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- OR4A47 | c.761T>G p.F254C | Missense Mutation (SNP) | VAF 7/103 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.376); called by muse, mutect2
- RSAD2 | c.613C>A p.Q205K | Missense Mutation (SNP) | VAF 15/89 reads (17%) | SIFT tolerated (0.29); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- SLC2A7 | c.626C>A p.A209D | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- SPRYD3 | c.116C>T p.A39V | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT tolerated (0.14); PolyPhen benign (0.143); called by muse, mutect2, varscan2
- TAF1L | c.1087G>C p.G363R | Missense Mutation (SNP) | VAF 10/138 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- TENM3 | c.3739G>A p.A1247T | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT tolerated (0.45); PolyPhen benign (0); called by muse, mutect2, varscan2
- ALDOA | c.208C>T p.L70= (on ENST00000642816 / NM_001243177.4; = p.L16= on NM_184041.5) | Silent (SNP) | VAF 6/34 reads (18%) | called by muse, mutect2, varscan2
- ALOX5AP | c.228A>G p.L76= | Silent (SNP) | VAF 12/51 reads (24%) | called by muse, mutect2, varscan2
- ARHGEF5 | c.4602C>T p.A1534= | Silent (SNP) | VAF 5/39 reads (13%) | catalogued as rs1040382186, COSV50209723; called by muse, mutect2, varscan2
- ARL1 | c.474G>A p.T158= | Silent (SNP) | VAF 20/106 reads (19%) | catalogued as rs1280135022, COSV55371020; called by muse, mutect2, varscan2
- COL6A1 | c.357G>A p.A119= | Silent (SNP) | VAF 10/38 reads (26%) | catalogued as rs747037863, COSV62612876, COSV62614791; ClinVar: likely benign / uncertain significance; called by muse, mutect2
- CSTF2T | c.1620A>T p.G540= | Silent (SNP) | VAF 11/85 reads (13%) | called by muse, mutect2, varscan2
- DDX24 | c.1680G>A p.V560= | Silent (SNP) | VAF 51/80 reads (64%) | catalogued as rs767350697, COSV58212349; called by muse, mutect2, varscan2
- DHRS7C | c.840C>T p.P280= (on ENST00000330255 / NM_001220493.2; = p.P279= on NM_001105571.3) | Silent (SNP) | VAF 10/32 reads (31%) | catalogued as COSV57650551; called by muse, mutect2, varscan2
- KPTN | c.640C>A p.R214= | Silent (SNP) | VAF 10/47 reads (21%) | catalogued as COSV57645017; called by muse, mutect2, varscan2
- MST1R | c.1992G>A p.P664= | Silent (SNP) | VAF 6/23 reads (26%) | catalogued as rs772234158; called by mutect2, varscan2
- NAGS | c.1107C>A p.T369= | Silent (SNP) | VAF 8/45 reads (18%) | called by muse, mutect2, varscan2
- PAPPA | c.3480G>A p.Q1160= | Silent (SNP) | VAF 7/33 reads (21%) | catalogued as COSV60282159; called by muse, mutect2, varscan2
- PIK3C2B | c.2958G>C p.L986= | Silent (SNP) | VAF 17/91 reads (19%) | catalogued as COSV100915978, COSV65810211, COSV65812471; called by muse, mutect2, varscan2
- PSPC1 | c.504C>T p.S168= | Silent (SNP) | VAF 9/47 reads (19%) | catalogued as COSV58887893; called by muse, mutect2, varscan2
- SCN5A | c.1380C>T p.S460= | Silent (SNP) | VAF 6/15 reads (40%) | catalogued as COSV61122478; called by muse, mutect2, varscan2
- SLITRK1 | c.1320G>T p.R440= | Silent (SNP) | VAF 13/69 reads (19%) | called by muse, mutect2, varscan2
- SOWAHB | c.111C>G p.P37= | Silent (SNP) | VAF 19/46 reads (41%) | catalogued as COSV57554295, COSV57554402; called by muse, mutect2, varscan2
- TCF3 | c.474G>C p.R158= | Silent (SNP) | VAF 5/14 reads (36%) | catalogued as rs755980732, COSV99513550; called by muse, mutect2, varscan2
- TEKT2 | c.912G>T p.L304= | Silent (SNP) | VAF 9/19 reads (47%) | catalogued as COSV52880871; called by muse, mutect2, varscan2
- TKTL2 | c.774A>G p.A258= | Silent (SNP) | VAF 6/32 reads (19%) | called by muse, mutect2, varscan2
- TTL | c.123G>A p.L41= | Silent (SNP) | VAF 8/18 reads (44%) | catalogued as COSV51974322; called by muse, mutect2, varscan2
- VIL1 | c.627C>T p.G209= | Silent (SNP) | VAF 10/28 reads (36%) | catalogued as rs767787005, COSV50287346; called by muse, mutect2, varscan2
- ZFC3H1 | c.1762T>C p.L588= | Silent (SNP) | VAF 31/76 reads (41%) | catalogued as COSV66432066; called by muse, mutect2, varscan2
- SSPOP | n.5698G>A | RNA (SNP) | VAF 13/22 reads (59%) | catalogued as rs766327797, COSV50487245; called by muse, mutect2, varscan2
